Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A616, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A616-01A (Primary Tumor).

Tumor ID:

ICD-O-3
Astrocytoma NOS 9400/3
Site: Supratentorial NOS
C71.0
JW 4/16/13

Microscopic Description:

Sections demonstrate a moderately hypercellular glial neoplasm with diffuse infiltration. The tumor cells have round to oval nuclei with mild atypia. Well-formed perinuclear halos are not seen. The neoplastic cell process form a loose fibrillary matrix. Mitotic figures are not seen. There is no microvascular proliferation or necrosis.

Addendum Discussion:

Neoplastic cells are immunoreactive for IDH1 but negative for p53. Only a few MIB-1 reactive cells are present with a labeling index but never exceeds a 0.6 percent.

Addendum Diagnosis:

Well differentiated astrocytoma (grade II)

MIB-1 LI= 0.6%

Prior MIB-1 History		✓
Case is (cirr):	✓	✓

Source: NCI Genomic Data Commons file 8493eb77-1472-4990-9ca4-6531cee90a40 (TCGA-HT-A616.65CCB3E5-56CE-4D6F-A6F5-4D1729A9BBF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).